Somatic mutation profile of tumor specimen TCGA-DU-7011-01A (aliquot TCGA-DU-7011-01A-11D-2024-08) from TCGA case TCGA-DU-7011, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 25.5 years (9,322 days).
Specimen TCGA-DU-7011-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6465e93f-6078-44c5-8cab-0df7a9331a37.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-7011-10A (Blood Derived Normal), aliquot TCGA-DU-7011-10A-01D-2024-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f7ee915-3d63-4b82-a0fd-e4fd43d642ae

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 13, Silent 4, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 20/78 reads (26%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 35/55 reads (64%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRE1 | c.2075T>C p.L692S | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99165917; called by muse, mutect2, varscan2
- ATRX | c.5817del p.D1940Ifs*15 | Frame Shift Del (DEL) | VAF 48/277 reads (17%) | catalogued as COSV100969996; called by mutect2, pindel, varscan2
- ATRX | c.1252C>T p.R418* | Nonsense Mutation (SNP) | VAF 49/190 reads (26%) | catalogued as rs1057523785, COSV64871339; called by muse, mutect2, varscan2
- CLCN4 | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.022); catalogued as COSV101074087; called by muse, mutect2, varscan2
- CLTCL1 | c.3226G>T p.D1076Y | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99595962; called by muse, mutect2
- CSPG4 | c.4555G>A p.G1519R | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763414673, COSV57903748; called by muse, mutect2, varscan2
- DNAI4 | c.257A>G p.Q86R | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV100925245; called by muse, mutect2
- IL27 | c.409C>G p.L137V | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV100112958; called by muse, mutect2
- KLHL15 | c.1162A>T p.T388S | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.711); catalogued as COSV100044455; called by muse, mutect2, varscan2
- LAMP1 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as rs768499433, COSV100208625; called by muse, mutect2, varscan2
- OR5P2 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.117); catalogued as rs374622867; called by muse, mutect2
- UBR2 | c.3637T>C p.C1213R | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100867546; called by muse, mutect2, varscan2
- CCR9 | c.139G>A p.A47T (on ENST00000357632 / NM_031200.3; = p.A35T on NM_006641.4) | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.476); called by muse, mutect2
- DCAF4L1 | c.555C>A p.A185= | Silent (SNP) | VAF 16/158 reads (10%) | catalogued as COSV100296025; called by muse, mutect2
- MAP2 | c.3159T>C p.F1053= | Silent (SNP) | VAF 54/142 reads (38%) | catalogued as COSV52306968, COSV99561849; called by muse, mutect2, varscan2
- PCLO | c.5775A>G p.T1925= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as COSV100438311; called by muse, mutect2, varscan2
- SERPINB11 | c.156G>A p.E52= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs763422032, COSV66957760; called by muse, mutect2, varscan2
